Surgical pathology report (de-identified scan), TCGA case TCGA-81-5911, project TCGA-GBM (Glioblastoma Multiforme), tissue source site CHI-Penrose Colorado, specimen TCGA-81-5911-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY**SPECIMEN**

- A. BRAIN - 1. Left occipital subcortical - FS
- B. BRAIN - 2. Left occipital subcortical - Fresh genome
- C. BRAIN - Left occipital subcortical - cusa suction container

CLINICAL INFORMATION

Left medial parietal mass.

COPY TO:

GROSS DESCRIPTION

The specimen is received in three parts, each labeled with the patient's name "[REDACTED]"

Part A is received fresh for frozen section and consists of four pieces of red-tan soft tissue. The specimen was additionally labeled "left occipital subcortical". A squash prep was made and the remaining tissue is entirely frozen as (FSA1). Tan tissue fragments measure an aggregate 10 x 9 x 3 mm. Frozen section diagnosis examined by [REDACTED] "high-grade astrocytoma, at least grade 3." The remaining tissue from FSA1 is submitted as (A1).

Part B is additionally labeled "left occipital subcortical. Fresh genome" and consists of fragments of tan-pink soft tissue. Approximately one-third to one half of the specimen is submitted for a cancer genome project. The remainder measures 2 x 1.7 x 0.4 cm in aggregate and is submitted entirely as (B1).

Part C is additionally labeled "left occipital subcortical-cusa container" and consists of a 3 x 2 x 0.4 cm aggregate of tan-pink tissue fragments in a red viscous background, which are submitted entirely as (C1).

MICROSCOPIC DESCRIPTION

Sections examined on multiple H&E-stained slides.

COMMENT:

[page 2 of 2]
H&E-stained sections demonstrate a hypercellular glial proliferation. Many of the cells have a gemistocytic appearance. There are also cells with enlarged nuclei and prominent nucleoli. Mitotic figures are identified. Focal tumoral cell necrosis and areas of vascular endothelial proliferation are present. As per requested, tissue from specimen B was submitted for the . This case has been reviewed by Dr. with concurrence. .

FINAL DIAGNOSIS

LEFT OCCIPITAL SUBCORTICAL, BIOPSY

- Glioblastoma multiforme (grade IV/IV astrocytoma).

LEFT OCCIPITAL SUBCORTICAL, BIOPSY

- Glioblastoma multiforme (grade IV/IV astrocytoma).

LEFT OCCIPITAL SUBCORTICAL-CUSA CONTENT

- Glioblastoma multiforme (grade IV/IV astrocytoma).
-

Source: NCI Genomic Data Commons file 67d441c9-a1b1-4488-b4ec-1a7881f4a01a (TCGA-81-5911.CEFF84E7-7DAC-4312-92FE-174CB3DA3205.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).